Somatic mutation profile of tumor specimen ALCH-AC6G-TTP1-B (aliquot ALCH-AC6G-TTP1-B-1-0-D-A49J-36) from ALCHEMIST case ALCH-AC6G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.5 years (16,997 days).
Specimen ALCH-AC6G-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37d14401-101b-4cf8-a5c5-21c5dd9fa87f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC6G-NB1-A (Blood Derived Normal), aliquot ALCH-AC6G-NB1-A-1-0-D-A49J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ae2ec3a-f5c2-4ec7-899a-cfabe4556b18

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Intron 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781642, COSV52677695, COSV53351693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AAK1 | c.1536T>G p.I512M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs1173492713; called by muse, mutect2
- COLEC11 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs896580554, COSV52591520; called by muse, mutect2
- KCNMA1 | c.3557G>A p.R1186Q (on ENST00000286628 / NM_001161352.2; = p.R1128Q on NM_002247.4) | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs200141207; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPAP1 | c.2645G>T p.R882I | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV61505417; called by muse, mutect2
- SYT14 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 126/1259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138939345; called by muse, mutect2, varscan2
- UHRF1 | c.751A>G p.T251A (on ENST00000612630 / NM_001290050.1; = p.T264A on NM_013282.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs767215556; called by muse, mutect2, varscan2
- ASCC3 | c.6167T>C p.L2056P | Missense Mutation (SNP) | VAF 145/688 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- C1orf74 | c.242T>A p.F81Y | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CP | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 40/556 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2
- GCNT3 | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- KDM4C | c.2267G>T p.C756F | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRIQ4 | c.1608del p.G537Efs*14 | Frame Shift Del (DEL) | VAF 23/180 reads (13%) | called by mutect2, pindel, varscan2
- LRRK2 | c.5147C>A p.S1716* | Nonsense Mutation (SNP) | VAF 19/234 reads (8%) | called by muse, mutect2
- MAGT1 | c.19T>C p.F7L (on ENST00000618282 / NM_001367916.1; = p.F39L on NM_032121.5) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOCS7 | c.1885A>G p.K629E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2
- DAAM2 | c.1737G>C p.L579= | Silent (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2
- MAFA | c.129C>T p.H43= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- SLC1A1 | c.279C>A p.R93= | Silent (SNP) | VAF 33/481 reads (7%) | catalogued as COSV99261576; called by muse, mutect2
- TBC1D8 | c.1458C>T p.Y486= | Silent (SNP) | VAF 33/248 reads (13%) | catalogued as rs368730178; called by muse, mutect2, varscan2
- THBS4 | c.2469C>T p.A823= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- ZNF415 | c.663C>T p.C221= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs375385270, COSV54704846; called by muse, mutect2, varscan2
- ZNF551 | c.12G>A p.P4= | Silent (SNP) | VAF 2/24 reads (8%) | catalogued as rs904174071, COSV99989684; called by muse, mutect2
- CDKL5 | c.2713+123C>T | Intron (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- CHRNB2 | c.*27C>T | 3'UTR (SNP) | VAF 32/162 reads (20%) | catalogued as COSV100872608; called by muse, mutect2, varscan2
- DCHS2 | n.6539T>A | RNA (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
- SDHA | c.1794+134C>G | Intron (SNP) | VAF 77/482 reads (16%) | called by muse, mutect2, varscan2
